Somatic mutation profile of tumor specimen TCGA-CQ-A4CB-01A (aliquot TCGA-CQ-A4CB-01A-11D-A25D-08) from TCGA case TCGA-CQ-A4CB, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 59.1 years (21,574 days).
Specimen TCGA-CQ-A4CB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba632d74-e157-43b6-bf70-6a2abcc63b7c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-A4CB-10A (Blood Derived Normal), aliquot TCGA-CQ-A4CB-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/772f4551-5ab8-4953-a05a-d5a592942c4c

The open-access MAF lists 93 somatic variants for this specimen: 76 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 16, Nonsense Mutation 3, Frame Shift Del 2, Nonstop Mutation 1, Splice Site 1, Intron 1, Frame Shift Ins 1, Splice Region 1, In Frame Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.653T>G p.V218G | Missense Mutation (SNP) | VAF 6/27 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555525743, COSV52690974, COSV52712839, COSV52761003; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC1 | c.1711A>G p.I571V | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1308042333, COSV100579581; called by muse, mutect2, varscan2
- BPIFB4 | c.1735G>A p.A579T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs747659473, COSV64951804; called by mutect2, varscan2
- CACNG3 | c.505T>A p.S169T | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.944); catalogued as COSV99136201; called by muse, mutect2, varscan2
- CCDC125 | c.677A>G p.K226R | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.039); catalogued as COSV101143603; called by muse, mutect2, varscan2
- CELSR1 | c.1200C>A p.F400L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99418337; called by muse, mutect2
- CHPF2 | c.932G>T p.G311V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.183); catalogued as COSV104377422, COSV99223086; called by muse, mutect2, varscan2
- CRLF3 | c.839G>A p.G280D | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.975); catalogued as COSV60837692; called by muse, mutect2, varscan2
- CRMP1 | c.1081C>T p.R361W | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61478869; called by muse, mutect2, varscan2
- DDIAS | c.2192C>T p.S731L | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.634); catalogued as COSV100231205; called by muse, mutect2, varscan2
- DIAPH2 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100232914; called by muse, mutect2, varscan2
- DOP1A | c.3373G>A p.E1125K | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.086); catalogued as rs1268858949, COSV99381938; called by muse, mutect2, varscan2
- DRC3 | c.551A>G p.D184G | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV100572729; called by muse, mutect2
- ESF1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 8/42 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.356); catalogued as COSV99176365; called by muse, mutect2
- FADS1 | c.433C>T p.L145F | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99952276; called by muse, mutect2, varscan2
- FAM135B | c.3865C>A p.R1289S | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52749802, COSV99418979, COSV99424084; called by muse, mutect2, varscan2
- FRMPD2 | c.789C>T p.R263= | Splice Region (SNP) | VAF 12/45 reads (27%) | catalogued as rs762835115, COSV100563844; called by muse, mutect2, varscan2
- GIT1 | c.673G>T p.E225* | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99838210; called by muse, mutect2, varscan2
- GUCY1A1 | c.911G>A p.G304D | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56650911; called by muse, mutect2, varscan2
- HDLBP | c.2975G>A p.G992E | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs776511784, COSV100190678; called by muse, mutect2, varscan2
- HPS5 | c.625A>G p.K209E (on ENST00000349215 / NM_181507.2; = p.K95E on NM_007216.4) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as COSV100834430; called by muse, mutect2
- HSPA8 | c.1848_1859del p.M621_G624del | In Frame Del (DEL) | VAF 16/96 reads (17%) | catalogued as rs765426437; called by mutect2, varscan2
- HUWE1 | c.3919G>C p.E1307Q | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.246); catalogued as COSV99472430; called by muse, mutect2, varscan2
- IL22RA1 | c.325A>T p.M109L | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs755773960, COSV99583015; called by muse, mutect2, varscan2
- IPO5 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.042); catalogued as rs632729, COSV55152763, COSV99847316; called by muse, mutect2, varscan2
- KALRN | c.125A>C p.K42T | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53782165, COSV99564455; called by muse, mutect2, varscan2
- KHNYN | c.746G>A p.R249K | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99249729; called by muse, mutect2, varscan2
- LCA5 | c.1601G>C p.G534A | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV100878124, COSV100878270; called by muse, mutect2, varscan2
- LIG4 | c.2671G>C p.E891Q | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as COSV63598397; called by muse, mutect2, varscan2
- MICAL3 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99261609; called by muse, mutect2, varscan2
- MRPL40 | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 38/250 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54272956; called by muse, mutect2, varscan2
- MRPL44 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs746155049, COSV99285219; called by muse, mutect2, varscan2
- MYH8 | c.5116G>A p.E1706K | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs776869211, COSV67961492, COSV67975339; called by muse, mutect2, varscan2
- MYT1 | c.3127G>A p.E1043K | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV100114699; called by muse, mutect2, varscan2
- NFATC1 | c.1321C>T p.H441Y | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99501663; called by muse, mutect2, varscan2
- NPHS1 | c.2741A>G p.D914G | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100799886; called by muse, mutect2
- OLFM4 | c.956G>C p.R319P | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.677); catalogued as rs144683972, COSV99524338; called by muse, mutect2, varscan2
- OR1C1 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.893); catalogued as COSV101376226; called by muse, mutect2, varscan2
- OR2A25 | c.202G>A p.V68I | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.137); catalogued as rs764155220, COSV101376390; called by muse, mutect2, varscan2
- PHACTR1 | c.233C>G p.S78C | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100277018; called by muse, mutect2
- PHF20L1 | c.3030G>C p.Q1010H | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.751); catalogued as COSV55191028, COSV99621322; called by muse, mutect2, varscan2
- PLEC | c.12958A>T p.I4320F (on ENST00000322810 / NM_201380.4; = p.I4210F on NM_000445.5) | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.497); catalogued as COSV100514273; called by muse, mutect2, varscan2
- PLEKHA6 | c.2608G>A p.E870K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs750159278, COSV99692079; called by muse, mutect2, varscan2
- PRKD1 | c.1599G>C p.E533D | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100120369, COSV59562787; called by muse, mutect2, varscan2
- QSER1 | c.550C>T p.R184* (on ENST00000399302; = p.R313* on NM_001076786.3) | Nonsense Mutation (SNP) | VAF 11/103 reads (11%) | catalogued as COSV67900027; called by muse, mutect2, varscan2
- RASEF | c.2186A>G p.K729R | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs775562004, COSV100906876; called by muse, mutect2, varscan2
- RBPJ | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV100623635; called by muse, mutect2, varscan2
- RNF157 | c.113T>C p.I38T | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as COSV99486984; called by muse, mutect2, varscan2
- SI | c.2209G>A p.G737S | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100015598; called by muse, mutect2
- SLC12A5 | c.2734G>A p.E912K (on ENST00000454036 / NM_001134771.2; = p.E889K on NM_020708.5) | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as rs565709821, COSV99716067; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC4A4 | c.1054-1G>T p.X352_splice (on ENST00000264485 / NM_001098484.3; = p.X308_splice on NM_003759.4) | Splice Site (SNP) | VAF 5/40 reads (13%) | catalogued as COSV99140232; called by muse, mutect2, varscan2
- STAC | c.1208G>T p.*403Lext*46 | Nonstop Mutation (SNP) | VAF 9/51 reads (18%) | catalogued as COSV99830034; called by muse, mutect2
- SUPT7L | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs531573550, COSV58135340; called by mutect2, varscan2
- TMEM222 | c.224G>A p.G75D | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100929965; called by muse, mutect2, varscan2
- TRABD | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.944); catalogued as rs773867189, COSV100326811; called by muse, mutect2, varscan2
- TRPC4 | c.2003A>T p.Y668F | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100156881; called by muse, mutect2, varscan2
- TTC3 | c.3518A>G p.K1173R | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV100695546; called by muse, mutect2, varscan2
- TYRO3 | c.920C>T p.S307F | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55487645; called by muse, mutect2, varscan2
- UBXN7 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.025); catalogued as COSV99581264; called by muse, mutect2, varscan2
- UIMC1 | c.1871G>A p.R624Q | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1053224906, COSV101022163, COSV65893656; called by muse, mutect2
- UNK | c.1968A>T p.E656D | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.935); catalogued as COSV99256768; called by muse, mutect2, varscan2
- UROC1 | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.201); catalogued as COSV99331487; called by muse, mutect2, varscan2
- USH2A | c.8035C>A p.H2679N | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.519); catalogued as COSV100234965; called by muse, mutect2, varscan2
- USHBP1 | c.226G>A p.G76S | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.027); catalogued as COSV99394247; called by muse, mutect2, varscan2
- VPS13A | c.1830G>T p.E610D | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs113804310, COSV100652818; called by muse, mutect2, varscan2
- WDR59 | c.17G>A p.S6N | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.026); catalogued as COSV100049347; called by muse, mutect2
- ZAN | c.1331C>G p.A444G | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.754); catalogued as COSV100769738; called by muse, mutect2, varscan2
- ZFAND1 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as rs1173671877, COSV55106673; called by muse, mutect2, varscan2
- ZNF311 | c.854A>G p.K285R | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV101014141; called by mutect2, varscan2
- ZNF493 | c.679T>G p.C227G | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs878974640, COSV100828643; called by muse, mutect2, varscan2
- ZNF555 | c.845A>G p.K282R | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.349); catalogued as COSV100514659; called by muse, mutect2, varscan2
- ZNF681 | c.414G>T p.Q138H | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.099); catalogued as COSV101267471; called by muse, mutect2
- KLHL41 | c.1321_1322del p.N441Cfs*5 | Frame Shift Del (DEL) | VAF 5/40 reads (13%) | called by mutect2, pindel, varscan2
- SNX14 | c.1581dup p.G528Wfs*4 (on ENST00000314673 / NM_001350535.1; = p.G475Wfs*4 on NM_020468.5 and 3 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 9/37 reads (24%) | called by mutect2, pindel, varscan2
- TRGV4 | c.206A>T p.D69V | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- WWP2 | c.2025del p.D675Efs*8 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel, varscan2
- AASS | c.1440G>A p.R480= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV100741782; called by muse, mutect2, varscan2
- ARID1A | c.5871C>T p.D1957= | Silent (SNP) | VAF 18/115 reads (16%) | catalogued as rs761246391, COSV100251634; called by muse, mutect2, varscan2
- ASTN1 | c.720C>T p.D240= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as rs757643505, COSV99921742; called by muse, mutect2, varscan2
- CDH11 | c.1779C>T p.C593= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs1418211293, COSV51750408; called by muse, mutect2, varscan2
- CEACAM19 | c.183G>A p.Q61= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV100715451; called by muse, mutect2
- DAPK3 | c.252G>A p.E84= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as rs779291482, COSV100009660; called by muse, mutect2, varscan2
- DGKD | c.522G>A p.P174= (on ENST00000264057 / NM_152879.3; = p.P130= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/109 reads (17%) | catalogued as rs769776662, COSV99896378; called by muse, mutect2, varscan2
- EIF3G | c.924C>G p.L308= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV99461317; called by muse, mutect2, varscan2
- FBH1 | c.1707A>G p.E569= (on ENST00000362091 / NM_178150.3; = p.E620= on NM_032807.4) | Silent (SNP) | VAF 8/116 reads (7%) | catalogued as COSV100758756; called by muse, mutect2
- FBN1 | c.5214C>T p.I1738= | Silent (SNP) | VAF 23/107 reads (21%) | catalogued as COSV100355112; called by muse, mutect2, varscan2
- GPR39 | c.1054C>A p.R352= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV100257760, COSV61415755; called by muse, mutect2, varscan2
- MUC17 | c.9669A>G p.P3223= | Silent (SNP) | VAF 56/342 reads (16%) | catalogued as rs776289616, COSV100073356; called by muse, mutect2, varscan2
- PCDHGA5 | c.267G>A p.R89= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as COSV99538590; called by muse, mutect2, varscan2
- PRPH2 | c.897T>C p.S299= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as COSV100028099; called by muse, mutect2, varscan2
- SCN1A | c.4980C>G p.L1660= (on ENST00000303395 / NM_001202435.3; = p.L1649= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as COSV100320485; called by muse, mutect2, varscan2
- TMEM38A | c.777C>T p.H259= | Silent (SNP) | VAF 32/169 reads (19%) | catalogued as rs186471011; called by muse, mutect2, varscan2
- USP49 | c.1876+17_1876+39del | Intron (DEL) | VAF 16/107 reads (15%) | called by mutect2, pindel
